TARGET case TARGET-15-SJMPAL043510 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/64fa8926-b5b1-459e-9171-8108484dc74e

Demographics
Sex at birth: female; Age at index: 10 years; Vital status: Dead; Days to death: 39 days.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 10.5 years (3,828 days); Year of diagnosis: 2011; Days to last follow up: 39 days.

Follow-up (1 entry)
- Days to follow up: 39 days; Event-free: no event (relapse, second malignancy or death) recorded through day 39; Year of follow up: 2011.

Biospecimens (1 sample)
- Sample TARGET-15-SJMPAL043510-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 39
- Protocol: DCOG
- Initial Therapy: ALL
- WHO ALAL Classification: T/M
- WHO Dx: T/M
